CPTAC case C3L-07080 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6cafa126-7f2b-4d7f-bb81-b5378a70332b

Demographics
Sex at birth: male; Race: white; Year of birth: 1946; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 74.9 years (27,373 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Residual disease: RX; Days to last known disease status: 1,391 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,391 days (3.8 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 5.5 cm; Lymph nodes tested: 14.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Days to treatment start: 19 days; Days to treatment end: 40 days; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 384 days (1.1 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 755 days (2.1 years); Disease response: Complete Response; ECOG performance status: 0.
- Days to follow up: 1,125 days (3.1 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07080-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -16 days; Initial weight: 155 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07080-22: Section location: Body, Antrum, Pylorus; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-07080-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -16 days; Initial weight: 477 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-07080-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -16 days; Method of sample procurement: Blood Draw.
